RC case RC-B5DM — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/acb72946-1c8b-429e-be43-89bedc739a1e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1950; Vital status: Alive.

Diagnoses (2)
1. Primary cutaneous gamma-delta T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9726/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 66.0 years (24,102 days); Year of diagnosis: 2016; Method of diagnosis: Incisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann arbor b symptoms described array: Night Sweats; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Iliac-Common / Lymph Node, Iliac-External / Lymph Node, Inguinal / Lymph node, NOS / Lymph Node, Para-Aortic / Bone marrow / Peripheral blood / Skin.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 4.1 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: EPOCH; Days to treatment start: 10 days; Days to treatment end: 105 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 143 days; Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the skin (histology not recorded by GDC). Laterality: Right; Age at diagnosis: 56.0 years (20,461 days); Year of diagnosis: 2007; Days to diagnosis: -3,641 days (-10.0 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -3,641 days (-10.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Days to follow up: 85 days; Disease response: Tumor Free.
- Day 1,543 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 1,686 days (4.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Lactate Dehydrogenase 621 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Positive [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80.3 kg; Height: 170 cm; BMI: 27.8.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diverticulitis.
- Timepoint category: Follow-up; Comorbidities: Diverticulitis / Nonalcoholic Fatty Liver Disease.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5DM-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B5DM-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide RC-B5DM-TBP1-A-1-0-CS1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 90; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
